TCGA case TCGA-24-2267 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/99a61986-7b23-46b5-99a4-efba6bad3766

Demographics
Sex at birth: female; Race: white; Age at index: 58 years; Vital status: Dead; Days to death: 1,446 days (4.0 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 58.3 years (21,293 days); Year of diagnosis: 1993; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIB; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: No macroscopic disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 6 days; Days to treatment end: 219 days; Number of cycles: 8; Treatment dose: 5,570 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Days to treatment start: 6 days; Days to treatment end: 219 days; Number of cycles: 8; Treatment dose: 7,740 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 580 days (1.6 years); Days to treatment end: 793 days (2.2 years); Number of cycles: 8; Treatment dose: 836 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 580 days (1.6 years); Days to treatment end: 793 days (2.2 years); Number of cycles: 8; Treatment dose: 2,524 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Altretamine; Initial disease status: Progressive Disease; Days to treatment start: 827 days (2.3 years); Days to treatment end: 946 days (2.6 years); Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Initial disease status: Progressive Disease; Days to treatment start: 983 days (2.7 years); Days to treatment end: 997 days (2.7 years); Number of cycles: 3; Treatment dose: 145 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 1,011 days (2.8 years); Days to treatment end: 1,011 days (2.8 years); Number of cycles: 1; Treatment dose: 2 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,172 days (3.2 years); Days to treatment end: 1,332 days (3.6 years); Number of cycles: 7; Treatment dose: 375 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 1,172 days (3.2 years); Days to treatment end: 1,332 days (3.6 years); Number of cycles: 7; Treatment dose: 2,302 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,347 days (3.7 years); Days to treatment end: 1,381 days (3.8 years); Number of cycles: 3; Treatment dose: 4,560 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 59.7 years (21,805 days); Days to diagnosis: 512 days (1.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 955 days (2.6 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 512 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 512 days (1.4 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,446 days (4.0 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Evidence of progression type: Convincing Image Source; Timepoint: Post Initial Treatment.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-2267-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1.3; Shortest dimension: 0.3.
  Slide TCGA-24-2267-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 4.
  Slide TCGA-24-2267-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 14.
- Sample TCGA-24-2267-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Carboplatin #1; Therapy regimen: Progression.
- Drug treatment 3: Pharmaceutical therapy drug name: Cisplatin #2-7; Therapy regimen: Progression.
- Drug treatment 4: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 5: Pharmaceutical therapy drug name: Navelbine; Therapy regimen: Progression.
- Drug treatment 7: Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 8: Pharmaceutical therapy drug name: Taxol; Therapy regimen: Progression.
- Drug treatment 9: Pharmaceutical therapy drug name: Hexalen; Therapy regimen: Progression.
- Drug treatment 9, Route of administrations: Route of administration: PO.
- Drug treatment 11: Pharmaceutical therapy drug name: Gemzar; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,446 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,446 days; disease-free interval: event (new tumor event after initially disease-free), 512 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 512 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-24-2267-01A-01D-0704-01): tumor purity 0.57, ploidy 2.84, whole-genome doublings 1.
